Somatic mutation profile of tumor specimen MBCProject_0103_T1_WES (aliquot MBCProject_0103_T1_WES_1) from CMI case MBCProject_0103, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 46.0 years (16,792 days).
Specimen MBCProject_0103_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6326f41-a4f2-4418-baca-b5eeb644994c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0103_SALIVA (Saliva), aliquot MBCProject_0103_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8384866c-df6d-473d-8f5e-7d97887da376

The open-access MAF lists 63 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 18, Intron 4, Nonsense Mutation 4, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD11 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as rs772764413, COSV99391621; called by muse, mutect2, varscan2
- ANO2 | c.185G>A p.R62H (on ENST00000356134 / NM_001278597.3; = p.R66H on NM_001278596.3) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs368125515; called by muse, mutect2, varscan2
- CHD5 | c.2845C>T p.R949W | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52411208; called by muse, mutect2, varscan2
- DSTYK | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs142986970; called by muse, mutect2, varscan2
- GATA3 | c.999dup p.G334Wfs*18 | Frame Shift Ins (INS) | VAF 125/743 reads (17%) | catalogued as COSV60517073; called by mutect2, pindel, varscan2
- GRIN2B | c.4312G>A p.V1438M | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs763699668; ClinVar: uncertain significance; called by muse, mutect2
- HEATR6 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 327/1956 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV51744194; called by muse, varscan2
- IGFN1 | c.2409G>A p.W803* (on ENST00000295591 / NM_001367841.1; = p.W3260* on NM_001164586.2) | Nonsense Mutation (SNP) | VAF 129/210 reads (61%) | catalogued as rs1255230945; called by muse, mutect2, varscan2
- KCNH5 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1318326471, COSV59763811; called by muse, mutect2
- KCNJ4 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV57857525; called by muse, mutect2
- MCTP2 | c.1788C>T p.S596= | Splice Region (SNP) | VAF 92/213 reads (43%) | catalogued as rs760003776; called by muse, mutect2, varscan2
- MDM4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV100914576; called by muse, varscan2
- MUC17 | c.11077A>C p.S3693R | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1373989671; called by muse, mutect2, varscan2
- NIN | c.3871C>T p.Q1291* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as rs1431278737; called by muse, mutect2, varscan2
- NOS1 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57609807; called by muse, mutect2, varscan2
- OR4K13 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs149397731; called by muse, mutect2, varscan2
- PC | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1358651584; called by muse, mutect2, varscan2
- SRPK1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs749473914; called by muse, mutect2, varscan2
- SYDE2 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1045985040; called by muse, mutect2, varscan2
- TMEM129 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs530038635; called by muse, mutect2, varscan2
- ASAP2 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.3389C>A p.P1130H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- C12orf65 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 24/720 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FIZ1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRIN1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- HCN4 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- IFNA7 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- INPP5F | c.2890G>T p.V964L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KIAA0319 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- LGR5 | c.369T>A p.N123K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MECP2 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTRF1 | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PAWR | c.125dup p.G44Rfs*83 | Frame Shift Ins (INS) | VAF 59/156 reads (38%) | called by mutect2, varscan2
- PHLDA3 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- PLSCR4 | c.242T>A p.V81D | Missense Mutation (SNP) | VAF 105/662 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- RASA1 | c.2255T>A p.L752Q | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHISAL2B | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRC | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TOP2A | c.1206del p.I403Lfs*6 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | called by mutect2, pindel, varscan2
- TPTE | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 18/561 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- ANK1 | c.2394C>T p.V798= | Silent (SNP) | VAF 316/1266 reads (25%) | called by muse, varscan2
- ANK1 | c.2346C>T p.V782= | Silent (SNP) | VAF 138/438 reads (32%) | catalogued as COSV99224137; called by muse, varscan2
- BNC2 | c.48A>G p.K16= | Silent (SNP) | VAF 49/213 reads (23%) | called by muse, mutect2, varscan2
- C2CD4D | c.834C>T p.V278= | Silent (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- CHD8 | c.2169C>T p.Y723= (on ENST00000646647 / NM_001170629.2; = p.Y444= on NM_020920.4) | Silent (SNP) | VAF 30/290 reads (10%) | catalogued as rs751220416, COSV101303140; called by muse, mutect2
- CYP2S1 | c.1416G>A p.L472= | Silent (SNP) | VAF 99/906 reads (11%) | called by muse, mutect2, varscan2
- EHHADH | c.864G>A p.S288= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs185059435; called by muse, mutect2, varscan2
- FCGBP | c.5589G>A p.T1863= | Silent (SNP) | VAF 28/850 reads (3%) | catalogued as rs1227400473; called by muse, mutect2
- FGFRL1 | c.657C>T p.Y219= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- KNOP1 | c.567G>A p.K189= | Silent (SNP) | VAF 64/203 reads (32%) | catalogued as rs1567519021; called by muse, mutect2, varscan2
- LCE2B | c.33G>A p.Q11= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as rs1260404633; called by muse, mutect2, varscan2
- MFSD4A | c.1188C>T p.F396= | Silent (SNP) | VAF 156/485 reads (32%) | catalogued as COSV100901609; called by muse, varscan2
- MFSD4A | c.1242C>G p.L414= | Silent (SNP) | VAF 180/591 reads (30%) | catalogued as COSV65656426; called by muse, varscan2
- MYO15A | c.2139G>A p.A713= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- OR2T12 | c.540C>T p.P180= | Silent (SNP) | VAF 98/512 reads (19%) | catalogued as rs1478943719, COSV58776993, COSV58779415; called by muse, mutect2, varscan2
- SV2C | c.597C>T p.L199= | Silent (SNP) | VAF 39/240 reads (16%) | catalogued as rs1292080692, COSV100456769; called by muse, mutect2, varscan2
- TGFBI | c.999G>A p.T333= | Silent (SNP) | VAF 46/334 reads (14%) | catalogued as rs754364652, COSV59352974; called by muse, mutect2, varscan2
- TLE5 | c.210C>G p.G70= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- ALS2CL | c.1436+17C>T | Intron (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500568 A>G | 5'Flank (SNP) | VAF 80/399 reads (20%) | called by muse, mutect2, varscan2
- CDIN1 | c.544+4728C>A | Intron (SNP) | VAF 16/72 reads (22%) | catalogued as rs748128335; called by muse, mutect2, varscan2
- FAF1 | c.1870-10644A>G | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- RPL38 | c.4-42T>G | Intron (SNP) | VAF 80/1497 reads (5%) | called by muse, mutect2
